Somatic mutation profile of tumor specimen TARGET-10-PARTSC-09A (aliquot TARGET-10-PARTSC-09A-01D) from TARGET case TARGET-10-PARTSC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,035 days).
Specimen TARGET-10-PARTSC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c280cbe3-bc9f-4cef-9705-294b96823bb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTSC-10A (Blood Derived Normal), aliquot TARGET-10-PARTSC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6166485d-7e08-4720-8b64-f3a7de0e7e2b

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4C12 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as rs141386333, COSV58859946, COSV58861260; called by muse, mutect2, varscan2
- AHI1 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ARID4B | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RSF1 | c.3599T>C p.V1200A | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SETBP1 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TCHH | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DDX11 | c.1275C>T p.Y425= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1251824258, COSV52506114; called by muse, mutect2, varscan2
- DLC1 | c.2832G>A p.P944= (on ENST00000276297 / NM_001348081.2; = p.P507= on NM_006094.5) | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV52302805; called by muse, mutect2, varscan2
- TENM3 | c.165G>A p.S55= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs1416349244; called by muse, mutect2, varscan2
- ART3 | c.847+52C>T | Intron (SNP) | VAF 20/66 reads (30%) | catalogued as rs751796232; called by muse, mutect2, varscan2
- ASIC3 | c.*38C>A | 3'UTR (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- CDH18 | c.-90G>T | 5'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, varscan2
